Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A97H, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A97H-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in lower esophagus, far from z line 3cm. It is ulcerated and invasive, with 8x6x6cm in size, soft and white-gray surface.

Microscopic Description: Mucosa is ulcerated. Tumor tissue arranges in the form of group or trabecular of tumor cells connecting each other. The malignant cells have moderate, light eosinophilic keratinized cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are present. Tumor invades in fat tissue. Stroma is fibrous and invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, Grade III, infiltrating adventitia

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Abdominal esophagus

Tumor size: 8 x 6 x 6 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adventitia

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site ^{CLCC} Esophagus, distal third
C15.5
^{path} Abdominal esophagus
C15.2
JW 11/7/14

Dual/Synchronous Primary		NOTED

Source: NCI Genomic Data Commons file ed2a6cf4-fb4c-4ce6-b85c-72b42e883569 (TCGA-IG-A97H.2C6041D1-F257-43E0-A851-CEE7E13483FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).